FM case AD11333 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/741ca5ea-9cbe-47fb-9aa0-9712c0602136

Male, 38.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
